Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6JN, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6JN-01A (Primary Tumor).

[page 1 of 2]
M

(171.0cm 110.9kg BSA: 2.3m²)

Accession:

Specimen Date/Time:

DIAGNOSIS

- (A) RIGHT LATERAL TONGUE LESION, BIOPSY:
INVASIVE SQUAMOUS CARCINOMA -- Well differentiated
- (B) RIGHT TONGUE FLOOR OF MOUTH TUMOR, PARTIAL GLOSSECTOMY:
INVASIVE SQUAMOUS CARCINOMA -- Well differentiated
Tumor Features:
Gross: Ulcerating
Size: 2.9 cm in largest dimension
Invasion: Present, depth 0.75 cm
Tumor Border: Pushing
Perineural Invasion: Absent
Vascular Invasion: Absent
Lymphocyte Infiltration: Marked

Mucosal and deep margins: Negative for invasive carcinoma
Dysplasia at mucosal edges: Absent

- (C) TEETH, REMOVAL:
Teeth, gross examination only.

- (D) LEVEL 1A, RIGHT NECK DISSECTION:
Three lymph nodes, no tumor present (0/3).

- (E) LEVEL 1B, RIGHT NECK DISSECTION:
Two lymph nodes, no tumor present (0/2).
Benign salivary gland.

- (F) LEVEL 2A, RIGHT NECK DISSECTION:
Eleven lymph nodes, no tumor present (0/11).

- (G) LEVEL 2B, RIGHT NECK DISSECTION:
Fibroadipose tissue, no tumor present.
Lymph nodes not identified.

- (H) LEVEL 3, RIGHT NECK DISSECTION:
METASTATIC SQUAMOUS CARCINOMA IN ONE OF ELEVEN LYMPH NODES (1/11).
Extracapsular extension, Present.

GROSS DESCRIPTION

- (A) RIGHT LATERAL TONGUE LESION -- A fragment of tan-pink soft tissue (0.5 x 0.2 x 0.2 cm). The specimen is entirely submitted for intraoperative diagnosis as A.

*FS/DX: INVASIVE SQUAMOUS CELL CARCINOMA.

- (B) RIGHT TONGUE FLOOR OF MOUTH TUMOR, PARTIAL GLOSSECTOMY -- A 4.8 x 4 x 2.2 cm. Centrally there is a large

ICD-O-3

Carcinoma, squamous
cell NOS 8070/3

Site Oral cavity c06.9
path

Overlapping lesion of
tongue 802.8
8/9/13

[page 2 of 2]
M

(171.0cm 110.9kg BSA: 2.3m²)

Accession:

Specimen Date/Time:

ulcerated verrucoid tan firm mass, 2.9 x 2.2 x 0.5 cm. There is a rim of normal mucosa (0.3 cm closest mucosal edge). The tumor invades to a depth of 0.5 cm grossly, 0.6 cm away from the deep margin. Representative sections are submitted for frozen section diagnosis.

SECTION CODE: B1, B2, circumferential mucosal margin; B3, radial section with deep margin. Remainder of the specimen entirely submitted.

*FS/DX: INVASIVE SQUAMOUS CARCINOMA, MUCOSAL AND DEEP MARGINS NEGATIVE FOR TUMOR. DEPTH OF INVASION 0.55 CM.

(C) TEETH – Two tan-yellow intact teeth measuring (1.5 and 0.2 cm in greatest dimension). Specimen is gross only.

(D) RIGHT NECK LEVEL 1A – Received is one segment of yellow-red fibroadipose tissue (3.5 x 3 x 1.8 cm). Within this is identified two lymph nodes, ranging in size from 0.4 – (0.8 x 0.6 x 0.6 cm). The specimen is representatively submitted with the fat entirely submitted.

SECTION CODE: D1, one lymph node, bisected; D2, one lymph node uncut; D3, representative fibroadipose tissue.

(E) RIGHT NECK LEVEL 1B – Received is one segment of yellow-red fibroadipose tissue (5 x 4 x 2 cm). Within this is identified two lymph nodes (0.8 x 0.6 x 0.6 cm in average). In addition, salivary gland tissue is present. Specimen is representatively submitted with the lymph nodes entirely submitted.

SECTION CODE: E1, one lymph node, bisected; E2, one lymph node, bisected; E3, representative portions of salivary gland.

(F) RIGHT NECK LEVEL 2A – Received is one segment of yellow-red fibroadipose tissue (4 x 4 x 3 cm). Within this is identified multiple potential lymph nodes ranging in size from 0.3 – 0.8 cm. Sectioning revealed large lymph node, shows a homogenous smooth red-tan cut surface. The specimen is representatively submitted with lymph nodes entirely submitted.

SECTION CODE: F1, one lymph node, bisected; F2, one lymph node, bisected; F3, four lymph nodes, uncut; F4, five lymph nodes, uncut.

(G) RIGHT NECK LEVEL 2B – Received is one segment of yellow-red fibroadipose tissue (3 x 2 x 2 cm). Examination does not obvious lymph nodes. The specimen is entirely submitted.

SECTION CODE: G1-G3, specimen in toto.

(H) RIGHT NECK LEVEL 3 – Received is one segment of yellow-red fibroadipose tissue (5 x 4 x 2 cm). Within this is identified multiple potential lymph nodes ranging in size from 0.3 – 1.2 cm. Sectioning large lymph node reveals homogenous brown-red smooth cut surface. The specimen is representatively submitted with lymph nodes entirely submitted.

SECTION CODE: H1, one lymph node, bisected; H2, one lymph node, bisected; H3, one lymph node, bisected; H4, three lymph nodes, uncut; H5, two lymph nodes, uncut; H6, two lymph nodes, uncut.

CLINICAL HISTORY

None given.

SNOMED CODES

T-51200, T-C4200, T-53000, M-80703, M-43000, M-80706

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

Diagnostic Discrepancy		☒
Pathologic Discrepancy		☒
Local Recurrence Discrepancy		☒
Local Recurrence Primary Site Discrepancy		☒
Local Recurrence Primary Site Discrepancy		☒
Case is (check):	☒ QUANTIFIED / ☒ DISQUALIFIED	

Source: NCI Genomic Data Commons file a7684d1f-372e-4663-b10b-5204d395bc31 (TCGA-CV-A6JN.079C639E-FA33-45BE-9CB8-BAC1B62DEC10.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).